Gene-level copy-number profile of tumor specimen ALCH-B37F-TTP1-A from ALCHEMIST case ALCH-B37F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.9 years (22,971 days).
Specimen ALCH-B37F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b0e037b-cb1c-4626-a17d-af261d2b53dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37F-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/d7a17058-e3a0-49e9-9b7e-5621f241d849

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 559; copy number 1: 4,504; copy number 2: 23,943; copy number 3: 17,526; copy number 4: 8,081; copy number 5: 2,537; copy number 6: 1,534; copy number 7: 91; copy number 8: 82; copy number 9: 42; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr4:183,418,890–183,419,805, 1 gene: AC112698.1.
- chr5:139,684,645–139,745,010, 2 genes (within-gene range 0–1): AC008667.1, RNU6-236P.
- chr8:24,950,955–24,957,110, 3 genes: NEFL, MIR6841, AC107373.2.
- chr8:43,542,076–43,674,591, 3 genes: AC134698.2, AC139365.2, AC139365.1.
- chr9:93,147,040–93,148,556, 1 gene: AL390760.1.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr10:34,675,635–34,676,041, 1 gene (within-gene range 0–2): RPS12P16.
- chr17:82,654,973–82,698,698, 2 genes: RAB40B, MIR4525.
- chr21:36,986,739–36,995,075, 2 genes (within-gene range 0–2): Y_RNA, MRPL20P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,287 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:778,747–9,729,114, 273 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:15,604,597–15,734,769, 7 genes, copy number 5 (within-gene range 4–5): CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2.
- chr1:20,732,880–21,176,888, 7 genes, copy number 5 (within-gene range 4–5): AL663074.1, HP1BP3, EIF4G3, RNU7-200P, MIR1256, RPS15AP6, AL627311.1.
- chr2:134,735,464–135,176,394, 9 genes, copy number 6 (within-gene range 3–6): CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B.
- chr2:169,479,480–173,282,036, 67 genes, copy number 5 (broad region; genes not listed).
- chr2:177,227,595–177,392,697, 1 gene, copy number 6 (within-gene range 4–6): NFE2L2.
- chr2:177,283,508–178,402,893, 23 genes, copy number 6: AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6.
- chr3:93,843,764–122,881,139, 415 genes, copy number 5–6 (broad region; genes not listed).
- chr3:142,449,007–142,578,733, 1 gene, copy number 5 (within-gene range 3–5): ATR.
- chr3:149,433,044–153,377,562, 82 genes, copy number 5 (broad region; genes not listed).
- chr3:160,495,007–161,503,942, 18 genes, copy number 6: KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr3:167,864,773–183,812,624, 251 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:187,932,764–198,123,232, 219 genes, copy number 5–6 (broad region; genes not listed).
- chr4:84,371,393–84,651,334, 4 genes, copy number 5: AC104063.1, NKX6-1, RPL3P13, CDS1.
- chr5:58,198–32,110,932, 463 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:32,124,716–32,174,319, 1 gene, copy number 6 (within-gene range 4–6): GOLPH3.
- chr5:32,174,471–45,895,970, 213 genes, copy number 6 (broad region; genes not listed).
- chr6:60,719,222–60,942,327, 5 genes, copy number 5: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr6:69,672,757–86,214,576, 222 genes, copy number 5–8 (broad region; genes not listed).
- chr7:6,663,974–6,708,901, 3 genes, copy number 7: AC073343.2, AC073343.1, ZNF12.
- chr7:7,078,302–8,004,053, 20 genes, copy number 5 (within-gene range 3–5): AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT.
- chr7:115,935,148–116,663,829, 12 genes, copy number 7: TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT.
- chr7:132,648,794–134,066,589, 14 genes, copy number 5: FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27.
- chr8:98,024,851–99,013,743, 26 genes, copy number 5 (within-gene range 3–5): RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1.
- chr8:118,923,557–127,742,951, 148 genes, copy number 5–7 (broad region; genes not listed).
- chr8:128,150,116–131,040,909, 29 genes, copy number 6–9 (within-gene range 4–9): MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1.
- chr8:140,657,900–141,002,216, 4 genes, copy number 6: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr9:31,644,576–33,182,865, 28 genes, copy number 6–9: HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P.
- chr9:60,914,407–61,453,030, 12 genes, copy number 8–9: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr13:114,234,887–114,337,626, 7 genes, copy number 6: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr15:90,266,317–90,314,499, 1 gene, copy number 5 (within-gene range 3–5): AC091167.6.
- chr15:90,281,848–90,502,239, 11 genes, copy number 5: AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr16:32,475,051–32,478,250, 1 gene, copy number 10: ABCD1P3.
- chr17:18,497,095–18,551,705, 4 genes, copy number 5 (within-gene range 2–5): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:73,737,854–75,896,951, 97 genes, copy number 6–9 (broad region; genes not listed).
- chr18:30,954,820–32,470,882, 47 genes, copy number 5: AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr19:52,949,379–56,078,801, 275 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:56,176,008–58,605,223, 180 genes, copy number 6 (broad region; genes not listed).
- chr20:39,329,014–40,043,889, 6 genes, copy number 5: ATG3P1, RN7SL680P, AL118523.1, HSPE1P1, LINC01370, AL133419.1.
- chr22:16,869,478–42,446,195, 1,078 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
